Surgical pathology report (de-identified scan), TCGA case TCGA-28-1745, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1745-01B (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A, G. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

TCGA-28-1745

B. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Necrosis - 30% of the tumor
- Proportion of the tumor - 100%

C. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100%
- Necrosis - 30%

D. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100%
- Proportion of necrosis - 45%

E. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100%
- Proportion of necrosis - 50%

F. BRAIN, LEFT TEMPORA, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor 100%
- Proportion of necrosis 50%

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the low 15% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

[page 2 of 4]
***** Addendum - Please See End of Report *****

PATIENT:

PATH #

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. [REDACTED] between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED] Accordingly, low expression of $\beta 1$ and $\beta 2$ in this tumor suggests a more favorable prognosis.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high-grade gliomas [REDACTED]

[REDACTED] Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

[REDACTED] Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma. [REDACTED]

Correspondingly, presence of a large fraction of cells immunonegative to pMAPK antibody in this case suggests a likelihood of this tumor being responsive to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with [REDACTED]

HISTORY: History of left temporal glioma and PS gliadel wafer placement

MICROSCOPIC:

This necrotizing glioma features microvascular proliferation, elongate, mitotically active nuclei and striking perivascular lymphocytic infiltrates.

IMMUNOSTAINS:

MGMT (A2): Weak staining in up to 15% of tumor nuclei

PTEN (A2): Loss (0+ stain)

pMAPK (A2): 0% of tumor nuclei and 0% of tumor cell cytoplasm is positive

Laminin beta-1 (8/411) (A2): Upregulated (2+ in endothelial cells)

Laminin beta-2 (9/421) (A2): Upregulated (2+ in endothelial cells)

GROSS:

A. LEFT TEMPORAL FS

Labeled with the patient's name, labeled "left temporal FS", and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a 1.1 x 0.9 x 0.8 cm tan-gray soft tissue fragment with focal areas of hemorrhage on the outer surface. Entirely submitted.

Slide key:

A1. Frozen section remnant - 1

A2. Remaining tissue - 3

B. LEFT TEMPORAL

Labeled with the patient's name, labeled "left temporal", and received fresh in the Operating Room and subsequently fixed in formalin is a 0.5 x 0.4 x 0.4 cm gray-tan soft tissue fragment. Entirely submitted.

[page 3 of 4]
***** Addendum - Please See End of Report *****

B1. (Study) - 1

C. LEFT TEMPORAL

Labeled with the patient's name, labeled "left temporal", and received fresh in the Operating Room and subsequently fixed in formalin is an aggregate of multiple gray-tan soft tissue fragments ranging from 0.2 to 0.4 cm in greatest dimension and aggregating to a measurement of 0.6 x 0.3 x 0.2 cm. Entirely submitted.

C1. (Study) - 3

D. LEFT TEMPORAL

Labeled with the patient's name, labeled "left temporal", and received fresh in the Operating Room and subsequently fixed in formalin is a 0.9 x 0.6 x 0.3 cm aggregate of multiple gray-tan soft tissue fragments ranging from 0.2 to 0.5 cm in greatest dimension. Entirely submitted.

D1. (Study) - 3

E. LEFT TEMPORAL

Labeled with the patient's name, labeled "left temporal", and received fresh in the Operating Room and subsequently fixed in formalin is a 1.0 x 0.4 x 0.3 cm aggregate of multiple gray-tan soft tissue fragments ranging from 0.2 to 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

E1. (Study) - 3

F. LEFT TEMPORAL

Labeled with the patient's name, labeled "left temporal", and received fresh in the Operating Room and subsequently fixed in formalin are two gray-tan soft tissue fragments measuring 1.0 x 0.4 x 0.2 cm and 0.6 x 0.4 x 0.2 cm. Entirely submitted.

Slide key:

F1. (Study) - 2

G. LEFT TEMPORAL (PERMANENT)

Labeled with the patient's name, labeled "left temporal tumor", and received in formalin is a 0.9 x 0.7 x 0.6 cm gray-tan soft tissue fragment with focal areas of hemorrhage on the outer surface. Entirely submitted.

G1. 2

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

PART A. LEFT TEMPORAL FS:

Glioblastoma

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by pathology and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed

[page 4 of 4]
***** Addendum - Please See End of Report *****

PATIENT:

PATH #:

FISH (FLUORESCENCE IN SITU HYBRIDIZATION) for EGFR

RESULTS:

Number of cells analyzed: 40

Ratio of EGFR/CEP: 1.0

Percentage of cells with ≥ 4 copies of EGFR: 5%

Amplification: NO

High Level of Polysomy: NO

INTERPRETATION:

1. Samples are interpreted as Positive if:
- a. EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells.
- b. When high level of polysomy ($\geq$ four copies of EGFR in $\geq 40\%$ of cells) is present.
2. Samples are interpreted as Negative if EGFR to CEP 7 signal ratio is < 2.0 or in the absence of high level of polysomy ($\geq$ four copies of EGFR).
3. Samples are considered inconclusive, requiring consult with the pathologist, when EGFR to CEP 7 signal ratio is ≥ 2.0 in $< 10\%$ of analyzed cells or when high level of polysomy ($\geq$ four copies of EGFR) is present in $< 40\%$ of cells. These cases also need to be co-read.

REFERENCES

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed

Source: NCI Genomic Data Commons file b486796e-563d-4469-8988-cd689d336d3b (TCGA-28-1745.E1B60428-26B4-4E7E-AD5E-EBDBC82D75D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).